Surgical pathology report (de-identified scan), TCGA case TCGA-19-0962, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-0962-01B (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT**FINAL DIAGNOSIS**

A.B.CLEFT PARIETAL TUMOR, TUMOR CENTER, TUMOR EDGE, RESECTION:

--HIGH GRADE ASTROCYTIC NEOPLASM, CONSISTENT WITH GLIOBLASTOMA, WHO GRADE IV.
SEE NOTE.

D. TUMOR CORTICAL SURFACE, RESECTION:

--FRAGMENTS OF SLIGHTLY HYPERCELLULAR BRAIN PARENCHYMA.

Note: This cellular GFAP-positive high grade astrocytic neoplasm shows heterogeneous morphology. The tumor consists of an infiltrating and a more discrete components. Focally, tumor extends into the subarachnoid space. Focal calcifications are noted. Multifocal palisading necrosis and microvascular proliferation are identified.

Tumor is positive for GFAP immunostain. Immunostains for synaptophysin and SMI-31 were used in the evaluation of this case. KI-67 immunostain is positive in scattered cells.

One or more of the reagents used to perform assays on this specimen MAY have contained components considered to be analyte specific reagents (ASR's). ASR's have not been cleared or approved by the U.S. Food and Drug Administration. These assays were developed and their performance characteristics determined by [REDACTED]. The assays were performed with appropriate positive and negative controls.

Electronically Signed Out By

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consult Diagnosis

A. Microscopic: Brain tumor, biopsy: High grade malignant glioma with scattered gemistocytes.

Clinical History:

(I) parietal tumor

Specimens Submitted As:

A: (L) PARIETAL TUMOR

B: TUMOR CENTER

C: TUMOR EDGE

D: TUMOR CORTICAL SURFACE

Gross Description:

A: Received fresh, for intraoperative consultation, labelled with the patient's name and number, are two irregular fragments of tan-white, soft tissue, 0.8 x 0.4 x 0.3 cm and 0.9 x 0.3 x 0.2 cm. A touch prep is performed on the tissue as well as a frozen section. The specimen is submitted entirely in two cassettes.

B: Received fresh, post fixed in formalin, labeled with the patient's name, and "B-tumor center", is an irregular fragment of pink tan, soft, cerebriform tissue measuring 2.9 x 1.4 x 1.4 cm. A portion of this specimen has been submitted to [REDACTED]. The remaining tissue is submitted in toto in two cassettes.

C: Received fresh, post fixed in formalin, labeled with the patient's name and number, and "C-tumor edge", are multiple irregular, opaque white to pink-tan, soft cerebriform tissue fragments measuring in aggregate 2.0 x 1.6 x 0.35 cm. Submitted in toto in one cassette.

[page 2 of 2]
[REDACTED]

D: Received fresh, post fixed in formalin, labeled with the patient's name and number, and "D-cortical surface", is an irregular fragment of pink-tan, soft, cerebriform tissue measuring 0.5 x 0.3 x 0.2 cm. Submitted in toto in one cassette.

Summary of Cassettes:

Specimen	Label	Site
A	1	representative sections, frozen section
	2	remainder of specimen

[REDACTED]

Source: NCI Genomic Data Commons file 6997bcb1-9bcc-4caa-94f5-aced49f2791e (TCGA-19-0962.679E30ED-7731-41C5-AF4F-701C4435395F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).